Somatic mutation profile of tumor specimen 0DNCOK from CCDI case PBCBFK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 14.7 years (5,375 days).
Specimen 0DNCOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 883edafc-fe0b-4ea5-a94d-d561c42e2547.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNCH2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4481cfb3-8980-4adb-8df1-c23a3236ebd9

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPAS1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 257/930 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55384498, COSV55386554, COSV55388056; called by muse, mutect2, varscan2
- ATG2A | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 98/291 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs759118533; called by muse, mutect2, varscan2
- FYCO1 | c.1091A>T p.H364L | Missense Mutation (SNP) | VAF 54/893 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- TOX3 | c.1179C>T p.P393= | Silent (SNP) | VAF 134/698 reads (19%) | called by muse, mutect2, varscan2
- TBC1D25 | c.124-15G>A | Intron (SNP) | VAF 201/865 reads (23%) | called by muse, mutect2, varscan2
